Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4981, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4981-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA - BP - 4981

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: SP: KIDNEY AND ADRENAL, RIGHT; RADICAL NEPHRECTOMY

2: SP: FALCIFORM LIGAMENT; EXCISION

DIAGNOSIS:

1. SP: KIDNEY AND ADRENAL, RIGHT; RADICAL NEPHRECTOMY

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 8.6 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

2. SP: FALCIFORM LIGAMENT; EXCISION

Benign fibrocollagenous and adipose tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh labeled "right kidney, right adrenal gland and lymph nodes" and consists of a portion of fibroadipose tissue and a kidney with attached ureter, renal vessels and perinephric fat weighing 667.5 g in total. The kidney measures 12.6 x 7.5 x 6.0 cm. The attached ureter measures 9.5 cm in length and 0.4 cm in diameter. The attached renal vein measures a 0.3 cm in length and 0.7 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified and measures 3.3 x 1.7 x 0.7 cm. The kidney is inked black and bivalved to reveal an 8.6 x 7.5 x 6.0 cm well-defined, yellow to light tan, lobulated tumor mass in the superior portion of the kidney. Grossly, the tumor appears to be confined within the renal capsule and compress the renal pelvis without perforating it. However, tumor thrombus is present within the renal vein. Sections through the remainder of the kidney reveal a pink brown parenchyma with a well-defined cortico-medullary junction. The cortex measures 0.5 cm and the calyces appear normal. The specimen is submitted for lymph node dissection. Representative sections are submitted for TPS and for permanent sections. Gross photos are taken.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

TRP -- tumor with adjacent renal pelvis, including tumor thrombus in renal vein

RP -- an additional renal pelvis representative section

K -- representative sections kidney

AD -- adrenal gland

PLN -- possible lymph nodes

2). The specimen is received in formalin labeled, "Falciform ligament" and consists of a segment of indurated fatty tissue measuring 7.5 x 6.5 x 2.5 cm. The specimen is serially sectioned to reveal a cylindrical white-tan fibrotic tissue measuring 2.5 cm in length by 0.7 cm in maximum diameter. The specimen is representatively sampled.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: KIDNEY AND ADRENAL, RIGHT; RADICAL NEPHRECTOMY

Block	Sect. Site	PCs
1	AD	1
2	K	2
2	PLN	2
1	RP	1
8	T	8
1	THF	1
2	TK	2
1	TRP	1
1	TSF	1
1	UVM	1

Part 2: SP: FALCIFORM LIGAMENT; EXCISION

Block	Sect. Site	PCs
3	U	5

Source: NCI Genomic Data Commons file 4dd30a14-42eb-4d6b-b762-657da28a3221 (TCGA-BP-4981.A51F871B-296D-4AAC-B9F7-91E0F3FAEFC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).